CGCI case BLGSP-71-06-00145 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2a587474-c6c3-4322-b1ad-a11f2d205bb4

Demographics
Sex at birth: male; Race: black or african american; Age at index: 5 years; Vital status: Dead; Days to death: 2 days.

Diagnoses (1)
1. Burkitt-like lymphoma: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Intra-abdominal lymph nodes; Classification of tumor: primary; Year of diagnosis: 2014; Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Endemic; Max tumor bulk site: Other; Sites of involvement: Eye / Peritoneum, NOS / Kidney, NOS / Abdomen / Pleura.
   Pathology details: Lymph node involved site: Retroperitoneal; Tumor largest dimension diameter: 10 cm.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 60; ECOG performance status: 3.
- Days to follow up: 1 day; Disease response: With Tumor.
- Days to follow up: 2 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.

Biospecimens (3 samples)
- Sample BLGSP-71-06-00145-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Retroperitoneal; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Needle Biopsy; Tissue collection type: Prospective.
- Sample BLGSP-71-06-00145-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-06-00145-12A: Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Days to sample procurement: 1 day; Method of sample procurement: Other; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Days from index date to last known alive: 1; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), atypical morphology; Extranodal site involvement: 5; Extranodal involvment other: Intra-abdominal masses,pleural effusion; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Tru-cut biopsy; Lymph nodes examined: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed: Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
